Surgical pathology report (de-identified scan), TCGA case TCGA-77-8140, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8140-01A (Primary Tumor).

[page 1 of 3]
Collected [REDACTED]

Histopathology Report

HISTORY

Right upper lobe mass. 1: Right lower lobe lung. 2: Right level 4 lymph node.
3: Right middle lobe lymph node.

MACROSCOPIC

Five specimens received:

1: The second specimen is labelled "right upper lobe for frozen section" and consists of a nodule measuring 17 x 9 x 6 mm.

Frozen section diagnosis:

Organising pneumonia with a BOOP pattern.

Phoned to [REDACTED]

[Residual frozen section fragments remnants blocked, 1A.]

2: The first specimen is labelled "right upper lobe nodule" and consists of a wedge of lung tissue measuring 20 x 13 x 5 mm. The tissue contains a pale glistening nodule measuring approximately 7 mm in diameter.

Frozen section diagnosis:

Organising pneumonia.

Phoned to [REDACTED]

[Frozen section remnants blocked, 2A. Remaining fragments sectioned into 4RS and blocked, 2B.]

3: The third specimen is labelled "right lower lobe" and consists of a right lower lobe of lung measuring 115 x 90 x 80 mm. The pleural surface appears largely puckered, extending from the diaphragmatic surface of the lung and from the posterior to anterior pleural surfaces. A large firm mass is palpable beneath the area of pleural puckering. On sectioning, a large tumour mass is confirmed, measuring 60 x 48 x 70 mm. The tumour has a cream to yellow cut surface with areas of grey to black mottling. The tumour appears to approach both the posterior and anterior and diaphragmatic surfaces. The tumour is approximately 6 mm away from the medial pleural margin. On opening of the bronchial tree, the tumour appears to arise from a bronchial branch approximately 10 mm away from the bronchial resection margin. A large vessel runs through the middle of the tumour. However it does not appear macroscopically invaded. The uninvolved lung parenchyma appears unremarkable. [Bronchial resection margin, 3A; peribronchial lymph nodes, 3B; tumour with anterior pleural margin, 3C; tumour with posterior pleural margin, 3D; tumour in relation to bronchus, 3E; vascular resection margin and section through tumour with large vessel, 3F; tumour with diaphragmatic pleural surface, 3G; uninvolved lung, 3H.]

[page 2 of 3]
Collected [REDACTED]

Histopathology Report

4: The fourth specimen is labelled "right lymph node" and consists of a lymph node measuring 10 x 8 x 6 mm. The node has a pinkish red cut surface and is soft. [Specimen bisected, wrapped and blocked in toto, 4A.]

5: The fifth specimen is labelled "middle lobe lymph node and consists of two lymph nodes, the first measuring 20 x 12 x 10 mm and the second 12 x 7 x 9 mm. Both nodes feel firm and on sectioning have a cream cut surface. [Each node bisected and one-half blocked, 5A]

MICROSCOPIC

1-2: The specimens are similar. Paraffin sections confirm the frozen section diagnosis of organising pneumonia. In areas the pneumonia has a BOOP-type pattern. Fibrinous exudate is present on the pleural surface. There is no evidence of malignancy.

3: Sections show a moderately to poorly differentiated squamous cell carcinoma. The tumour shows focal clear cell change. It is subpleural and there is a suspicion of pleural invasion in an area of pleural scarring. Fibrinous exudate but no tumour is present on the pleural surface. Focal blood vessel invasion is present but there is no lymphatic permeation. Many of the pulmonary arteries show fibrous intimal thickening and focally there are features of a previously recanalised thrombus. The vessel infiltrated by carcinoma appears distal to this. No perineural permeation is identified. The lesion is well clear of the bronchial resection margin but there is mild active chronic inflammation, squamous metaplasia with moderate dysplasia. Metastatic deposits are noted within a peribronchial lymph node. The adjacent lung shows evidence of emphysema, organising pneumonia and nodules of luminal fibrin.

4: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

5: Sections of the lymph nodes show extensive replacement by metastatic squamous cell carcinoma.

SUMMARY

Right lower lobe and lymph nodes:

- 1: Moderately to poorly differentiated squamous cell carcinoma; 70 mm in maximal dimension.
- 2: Blood vessel permeation identified but no lymphatic or perineural invasion present.
- 3: Possible pleural invasion identified, special stains being performed; clear of bronchial margin.
- 4: Peribronchial and right middle lobe lymph node metastases.
- 5: T2N1MX

[page 3 of 3]
Collected

Histopathology Report

SUPPLEMENTARY REPORT
Carcinoma invades through the inner elastic lamina of the pleura but not through the outer lamina or convincingly into the visceral pleura itself.

c.c. Lung Cancer Registry

Source: NCI Genomic Data Commons file 61c4deeb-c7e5-4627-9957-c9ad186b1e3e (TCGA-77-8140.C8A18693-4875-45D9-8A31-ED04B8B3566C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).